MMRF case MMRF_2231 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0470e569-45b7-4ad8-bee1-1fc70059a74d

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.1 years (27,049 days); ISS stage: I; Days to last known disease status: 882 days (2.4 years); Days to last follow up: 882 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 64 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 130 days; Days to treatment end: 130 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days; Days to treatment end: 232 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 233 days; Days to treatment end: 233 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -19 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 44.8 mg/dL; Immunoglobulin G 31.2 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 7.8 g/dL; Glucose 5.12 mmol/L.
- Day 64 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.34 mg/dL; Immunoglobulin G 16.6 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 292 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 5.23 mmol/L.
- Day 168 (ECOG 0): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.99 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.02 µg/mL; Lactate Dehydrogenase 5.37 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 4.24 mmol/L.
- Day 255 (ECOG 0): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.959 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.95 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.21 µg/mL; Lactate Dehydrogenase 6.38 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 38.9 µmol/L; Blood Urea Nitrogen 1.43 mmol/L; Calcium 2.13 mmol/L; Albumin 30 g/L; Total Protein 5.4 g/dL; Glucose 6.05 mmol/L.
- Day 315 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 8.21 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 4.13 mmol/L.
- Day 406 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 9.86 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 4.62 mmol/L.
- Day 497 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.59 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.63 g/L; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 5.01 mmol/L.
- Day 592 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.56 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 5.12 mmol/L.
- Day 683 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.78 mg/dL; Immunoglobulin G 9.87 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.66 g/L; Lactate Dehydrogenase 2 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 5.06 mmol/L.
- Day 784 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.43 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.85 g/L; Lactate Dehydrogenase 12.2 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 5.17 mmol/L.
- Day 882 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.61 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.65 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -19: Weight: 68 kg; Height: 149 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2231_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -19 days.
- Sample MMRF_2231_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -19 days.
